Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A13V, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A13V-01A (Primary Tumor).

[page 1 of 5]
Clinical Diagnosis & History:

Left thyroid lobe papillary carcinoma.

Specimens Submitted:

- 1: SP: Prelaryngeal lymph node (delphian) (fs)
- 2: SP: Right paratracheal node
- 3: Thyroid and central compartment lymph node, total thyroidectomy and lymphadenectomy
- 4: SP: Left paratracheal lymph node
- 5: SP: Thymus

DIAGNOSIS:

1. LYMPH NODE, DELPHIAN, PRELARYNGEAL, LYMPHADENECTOMY:
-ONE LYMPH NODE POSITIVE FOR METASTATIC PAPILLARY THYROID CARCINOMA (1/1).
- THE LYMPH NODE MEASURES 1.4 CM IN GREATEST DIMENSION WITH THE METASTATIC FOCUS MEASURING 0.8 CM.
-NOT EXTRANODAL EXTENSION BY TUMOR IS NOTED.
2. LYMPH NODES, RIGHT PARATRACHEAL NODE, LYMPHADENECTOMY:
-TEN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/10).

ICD - 0 - 3

Carcinoma, Papillary, thyroid

8260/3

lw

11/16/10

Site: thyroid, NOS C73.9

3. Thyroid and central compartment lymph node, total thyroidectomy and lymphadenectomy:

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Calcification of non-psammoma type

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 2.9 cm.

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

[page 2 of 5]
Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type: INPATIENT
Additional Copy to:

Clinical Diagnosis & History:

Left thyroid lobe papillary carcinoma.

Specimens Submitted:

- 1: SP: Prelaryngeal lymph node (delphian) (fs)
- 2: SP: Right paratracheal node
- 3: Thyroid and central compartment lymph node, total thyroidectomy and lymphadenectomy
- 4: SP: Left paratracheal lymph node
- 5: SP: Thymus

DIAGNOSIS:

1. Lymph node, delphian, prelaryngeal, lymphadenectomy:
-ONE LYMPH NODE POSITIVE FOR METASTATIC PAPILLARY THYROID CARCINOMA (1/1).
- THE LYMPH NODE MEASURES 1.4 CM IN GREATEST DIMENSION WITH THE METASTATIC FOCUS MEASURING 0.8 CM.
-NOT EXTRANODAL EXTENSION BY TUMOR IS NOTED.
2. Lymph nodes, right paratracheal node, lymphadenectomy:
-TEN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/10).
3. Thyroid and central compartment lymph node, total thyroidectomy and lymphadenectomy:
Tumor Type:
Papillary carcinoma, classical type

Histologic Grade:
Well differentiated

Mitotic Activity:
Not identified

Tumor Necrosis:
Not identified

Other Tumor Features:
Calcification of non-psammoma type

Tumor Location:
Left lobe

Tumor Size:
Greatest diameter is 2.9 cm.

Tumor Encapsulation:
Partially surrounded

Blood Vessel Invasion:

[page 3 of 5]
Not identified

Extrathyroid Extension:

Invades:extrathyroidal fibroadipose tissue

Surgical Margins:

Tumor is noted very close less than 0.2 mm from the inked margin

Tumor Multicentricity:

Microscopic foci present

A focus of papillary microcarcinoma is noted in the left lobe measuring 0.1 cm in greatest dimension

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Exhibits chronic lymphocytic thyroiditis

Parathyroid Glands:

Not identified

Lymph Nodes:

Perinodal (extracapsular) extension not identified

Four out of six lymph node (4/6) positive for metastatic thyroid carcinoma. The largest metastatic lymph node measures 0.5 cm and it is almost entirely replaced by carcinoma

4. Lymph Nodes, Left Paratracheal, Dissection:
-THREE OUT OF THREE LYMPH NODES POSITIVE FOR METASTATIC PAPILLARY THYROID CARCINOMA (3/3)
- THE LARGEST METASTATIC LYMPH NODE MEASURES 0.7 CM IN GREATEST DIMENSION, AND IT IS ALMOST ENTIRELY REPLACED BY CARCINOMA.
-FOCAL EXTRANODAL EXTENSION IS NOTED.
5. THYMUS, EXCISION:
- BENIGN THYMIC TISSUE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh for frozen section consultation, labeled "prelaryngeal lymph node r/o carcinoma" and consists of a lymph node measuring 1.7 cm in greatest dimension. The lymph node is bisected and entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

R- remainder tissue

2) The specimen is received in formalin labeled "right peritracheal node" and consists of two firm pink tan lymph nodes ranging from 0.5 cm up to 0.6 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN-lymph nodes

3) The specimen is received fresh, labeled "total thyroid gland and central compartment lymph node" and consists of a thyroid weighing 22 g. The right lobe measures 3.8 x 2.3 x 1.5 cm, the left lobe measures 4.2 x 2.5 x 1.8 cm and the isthmus has a pyramidal shape and measures 1.4 x 0.6 x 0.4 cm. There are multiple pink tan lymph nodes with surrounding fat attached to the

[page 4 of 5]
inferior central aspect of the isthmus, ranging from 0.5 cm up to 0.7 cm in greatest dimension. All identified lymph nodes are submitted. The external surface is covered by a thin fibrous capsule, with an additional adhered portion of skeletal muscle along the left lower pole measuring 1.8 x 1.1 x 0.9 cm. The posterior surface of the specimen is inked black, and the anterior is inked blue. The specimen is sectioned to reveal a 2.9 x 2.5 x 1.8 cm yellow white papillary nodule located in the left mid to lower pole. A central portion of the nodule is submitted for TPS, the nodule to capsule and parenchyma interface is block out and entirely submitted. Sections through the remaining tissue reveal a red brown homogeneous grossly unremarkable parenchyma. The remaining uninvolved thyroid tissue is submitted. Representative sections are submitted.

Summary of sections:

N - nodule
RL - right lobe
LL - left lobe
IS - isthmus
BLN - bisected lymph nodes
LN-lymph nodes

4) The specimen is received in formalin labeled "left paratracheal lymph node" and consists of three firm lymph nodes with attached fatty fibrous tissue ranging from 0.5 cm up to 0.6 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN-lymph node
BLN-bisected lymph nodes

5) The specimen is received in formalin, labeled "thymus" and consists of a smooth tan-white soft tissue resection measuring 11.8 x 2.5 x 0.7 cm, weighing 10g. The specimen is inked black and sectioned to reveal a homogenous yellow tan cut surface. Representative sections are submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: SP: Prelaryngeal lymph node (delphian) (fs)

Block	Sect. Site	PCs
1	FSC	1
1	R	2

Part 2: SP: Right paratracheal node

Block	Sect. Site	PCs
1	In	1

Part 3: Thyroid and central compartment lymph node, total thyroidectomy and lymphadenectomy

Block	Sect. Site	PCs
2	BLN	2
2	IS	2
4	LL	4
2	LN	2
10	N	10
7	RL	7

Part 4: SP: Left paratracheal lymph node

Block	Sect. Site	PCs
2	bln	2
1	In	1

Part 5: SP: Thymus

Block	Sect. Site	PCs
-------	------------	-----

[page 5 of 5]
Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: Prelaryngeal lymph node (delphian) (fs): Metastatic papillary carcinoma
PERMANENT DIAGNOSIS: Same

Source: NCI Genomic Data Commons file cac59695-e874-4ca5-9b73-f90fa9781e24 (TCGA-DJ-A13V.5967D6EE-E853-4756-85D0-69BA833680D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).